Somatic mutation profile of tumor specimen TARGET-20-PARGVC-04A (aliquot TARGET-20-PARGVC-04A-01D) from TARGET case TARGET-20-PARGVC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,802 days).
Specimen TARGET-20-PARGVC-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef59e7cb-3994-4739-a8a4-489d7fca3d90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGVC-14A (Bone Marrow Normal), aliquot TARGET-20-PARGVC-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/476f4fe3-b3ef-40ce-bc7a-a97e6a7626d3

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/253 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DAG1 | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58185767; called by muse, mutect2, varscan2
- LIG3 | c.208T>C p.Y70H | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV52009256; called by muse, mutect2, varscan2
- ME1 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 164/479 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs752555482, COSV63843067; called by muse, mutect2, varscan2
- PTPRT | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 146/452 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs758531464, COSV61967363; called by muse, mutect2, varscan2
- TRERF1 | c.1140_1141insCTCC p.E381Lfs*24 | Frame Shift Ins (INS) | VAF 22/120 reads (18%) | catalogued as COSV61674938; called by mutect2, pindel, varscan2
- UBE4B | c.3571C>T p.R1191W (on ENST00000343090 / NM_001105562.3; = p.R1062W on NM_006048.5) | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1419508654, COSV53536654; called by muse, mutect2, varscan2
- SLC17A8 | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 39/431 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DZIP1L | c.639G>C p.R213= | Silent (SNP) | VAF 24/775 reads (3%) | catalogued as COSV59523405; called by muse, mutect2
- PPP1R15A | c.1992G>A p.A664= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs186438232; called by muse, mutect2, varscan2
- SRP72 | c.1732C>T p.L578= | Silent (SNP) | VAF 42/154 reads (27%) | catalogued as COSV61378483; called by muse, mutect2, varscan2
